Somatic mutation profile of tumor specimen TCGA-EE-A2M8-06A (aliquot TCGA-EE-A2M8-06A-12D-A196-08) from TCGA case TCGA-EE-A2M8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.4 years (20,221 days).
Specimen TCGA-EE-A2M8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c9feaa6-4a4d-47bc-bf07-5ddc0a9b20ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2M8-10A (Blood Derived Normal), aliquot TCGA-EE-A2M8-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80b0f16a-e23e-4e82-b68f-3a44066e516d

The open-access MAF lists 114 somatic variants for this specimen: 72 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 39, Nonsense Mutation 4, Splice Site 1, Intron 1, RNA 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANK3 | c.12673C>T p.R4225* (on ENST00000280772 / NM_001320874.2; = p.R849* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV55047406; called by muse, mutect2, varscan2
- ARHGAP25 | c.1361C>T p.A454V (on ENST00000409202 / NM_001007231.3; = p.A446V on NM_014882.3) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV54906524; called by muse, mutect2, varscan2
- BSN | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56525032; called by muse, mutect2, varscan2
- CCHCR1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV66161630; called by muse, mutect2, varscan2
- CEP350 | c.2758A>G p.K920E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62608152; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CNTNAP2 | c.3457T>A p.F1153I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as COSV100665655; called by mutect2, varscan2
- CNTNAP4 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56695021; called by muse, mutect2, varscan2
- CPE | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV68582027; called by muse, mutect2, varscan2
- CXXC1 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs369886387; called by muse, mutect2, varscan2
- DNAJB13 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60105124; called by muse, mutect2, varscan2
- EYA1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.069); catalogued as COSV100378743, COSV58167825; called by muse, mutect2, varscan2
- F11 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV53005022, COSV53008842; called by mutect2, varscan2
- FBN2 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52536239; called by muse, mutect2, varscan2
- GCN1 | c.4769G>A p.R1590K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV56113097; called by muse, mutect2
- GPR50 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54441852; called by muse, varscan2
- HDAC9 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.829); catalogued as COSV67767779; called by mutect2, varscan2
- HLF | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.769); catalogued as COSV56831353; called by mutect2, varscan2
- HLTF | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV59502817; called by muse, mutect2, varscan2
- IFT122 | c.3400A>G p.I1134V (on ENST00000348417 / NM_052989.3; = p.I1075V on NM_018262.4) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs754333037, COSV56206668; called by muse, varscan2
- ITGAM | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761622995, COSV54940889; called by mutect2, varscan2
- ITIH3 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201794632, COSV101406916; called by muse, mutect2, varscan2
- KRT28 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs200406506, COSV60683823, COSV60684962; called by muse, mutect2, varscan2
- KRT32 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56786238; called by muse, mutect2
- KRT6A | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV58107014; called by muse, mutect2, varscan2
- LIG1 | c.2636G>C p.R879P | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54394905; called by muse, mutect2
- LONRF2 | c.690T>A p.D230E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66541862; called by muse, mutect2, varscan2
- MAGEB18 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV57465290; called by muse, varscan2
- MCUR1 | c.618T>A p.D206E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV63958195; called by muse, mutect2, varscan2
- MTM1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782709837, COSV60334599; called by muse, mutect2, varscan2
- MUC16 | c.15346G>A p.E5116K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.041); catalogued as rs866107833, COSV67449897; called by muse, mutect2, varscan2
- NEXMIF | c.4345C>T p.R1449C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946737858, COSV50075185; called by muse, varscan2
- NEXMIF | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50038353; called by muse, mutect2
- NKAP | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV65056802; called by mutect2, varscan2
- NLGN3 | c.1243G>A p.E415K (on ENST00000358741 / NM_181303.2; = p.E395K on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV62444769; called by muse, mutect2, varscan2
- NPAP1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV61510086; called by muse, mutect2, varscan2
- NPHS1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs555255264, COSV100800437, COSV62287222; called by mutect2, varscan2
- OR5D13 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV62334874; called by muse, mutect2, varscan2
- PCMTD1 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV62124605; called by muse, mutect2, varscan2
- PDE1A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs775065809, COSV59521241; called by muse, mutect2, varscan2
- PKHD1 | c.6656C>T p.S2219L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as CX100434, COSV61890103; called by mutect2, varscan2
- PLCB4 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53813335; called by muse, mutect2
- PMFBP1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52829998; called by muse, mutect2
- PREX2 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV55793316; called by muse, mutect2, varscan2
- PRSS21 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50051989; called by muse, mutect2, varscan2
- PSMA6 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as rs78322008, COSV99809145; called by mutect2, varscan2
- PSMA6 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99809147; called by muse, mutect2, varscan2
- RNF148 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV57379311; called by mutect2, varscan2
- ROBO2 | c.2497A>T p.I833F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV59931777; called by muse, mutect2, varscan2
- ROBO3 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV67302233; called by muse, mutect2
- S100A7A | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); catalogued as rs1214821036, COSV61331083; called by muse, mutect2
- SEMA4F | c.1750G>T p.V584F | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV100335950; called by muse, mutect2, varscan2
- SGCZ | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV66026203, COSV66035179; called by muse, mutect2, varscan2
- SLC1A3 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as rs1449022570, COSV54319106; called by muse, mutect2, varscan2
- SLC24A3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV60120494; called by muse, mutect2, varscan2
- SLC6A14 | c.1756del p.I586Ffs*12 | Frame Shift Del (DEL) | VAF 20/165 reads (12%) | catalogued as COSV100902495; called by mutect2, pindel, varscan2
- TEX13A | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as COSV61173775; called by muse, varscan2
- TLE4 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV54638848; called by muse, varscan2
- TLK2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.118); catalogued as rs1390955015, COSV58304451; called by mutect2, varscan2
- TMEM132E | c.1409C>T p.P470L (on ENST00000321639; = p.P560L on NM_001304438.2) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV58699650; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.506T>A p.L169* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100552486; called by muse, mutect2, varscan2
- TNR | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV54905915; called by muse, varscan2
- TTN | c.68559T>G p.S22853R (on ENST00000591111; = p.S15429R on NM_003319.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | PolyPhen benign (0.246); catalogued as COSV60261259; called by muse, mutect2, varscan2
- USH1G | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.123); catalogued as rs768235452, COSV100140421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.2249A>G p.N750S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV56415843; called by muse, mutect2, varscan2
- VASH2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.961); catalogued as COSV55119009; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1269T>A p.D423E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV60158269; called by muse, mutect2, varscan2
- ZNF436 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV58359178; called by muse, mutect2, varscan2
- ZNF558 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56864103; called by muse, mutect2, varscan2
- ZNF568 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as rs1387648243, COSV61741988; called by muse, mutect2, varscan2
- OSMR | c.1363-1G>A p.X455_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ABL2 | c.336C>T p.F112= (on ENST00000502732 / NM_007314.4; = p.F97= on NM_005158.5) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs200298102, COSV61017839; called by mutect2, varscan2
- ACSM2A | c.1437G>A p.E479= (on ENST00000219054; = p.E400= on NM_001308169.2) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs149737523, COSV54587379; called by mutect2, varscan2
- ADGRV1 | c.7449G>A p.R2483= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV67978627; called by muse, mutect2, varscan2
- AKNAD1 | c.2187G>A p.R729= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV62202118; called by muse, mutect2, varscan2
- BPIFB4 | c.1233C>T p.P411= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV64952001; called by muse, mutect2, varscan2
- BRSK2 | c.1167G>A p.T389= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs370646463; called by mutect2, varscan2
- BSPRY | c.1200C>T p.I400= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs373895411; called by mutect2, varscan2
- C10orf120 | c.486G>A p.V162= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV61492469; called by mutect2, varscan2
- CNGB1 | c.4T>C p.L2= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99202337; called by muse, mutect2
- CNTNAP2 | c.3456C>T p.L1152= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs781282185, COSV100665506, COSV100665654; called by muse, mutect2, varscan2
- DNAH5 | c.5697C>T p.I1899= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV54244631, COSV54247801; called by muse, mutect2, varscan2
- FLNC | c.1296T>C p.G432= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV57962073; called by muse, mutect2, varscan2
- FLNC | c.4965C>T p.G1655= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV57962084; called by muse, mutect2, varscan2
- FMO2 | c.276G>A p.R92= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV52947130; called by muse, mutect2, varscan2
- GATB | c.1512C>T p.L504= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56132620; called by muse, mutect2, varscan2
- GCN1 | c.4503C>T p.S1501= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV56104903; called by muse, mutect2, varscan2
- GLP2R | c.666C>T p.I222= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV52328170; called by muse, mutect2, varscan2
- GPR179 | c.2929C>T p.L977= (on ENST00000621958; = p.L976= on NM_001004334.4) | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- GRM3 | c.612C>T p.I204= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100862488, COSV100862768; called by mutect2, varscan2
- GUCY2F | c.954C>T p.S318= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV54306748; called by muse, mutect2
- HSPBAP1 | c.699C>T p.F233= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV60243408; called by muse, mutect2, varscan2
- HTATSF1 | c.603G>A p.L201= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV54480633; called by muse, varscan2
- ISG20 | c.126C>T p.F42= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV60144327; called by muse, mutect2, varscan2
- KRT15 | c.963G>A p.E321= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs1191500257, COSV54181318; called by muse, mutect2, varscan2
- KRTAP10-8 | c.597C>T p.T199= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs1265436462, COSV58167018; called by muse, mutect2, varscan2
- MCTP2 | c.150C>T p.L50= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV59148571; called by mutect2, varscan2
- NWD1 | c.3483G>A p.G1161= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV60342893; called by muse, mutect2, varscan2
- POC1A | c.996C>T p.F332= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV56592989; called by muse, mutect2, varscan2
- PTCHD4 | c.1347C>T p.F449= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV59793332; called by mutect2, varscan2
- PTPN2 | c.1074G>A p.K358= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58998541; called by muse, mutect2, varscan2
- PTPRN2 | c.1761G>A p.L587= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as COSV67027970; called by muse, mutect2
- RASGRF1 | c.2814G>A p.R938= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV67250879; called by muse, mutect2, varscan2
- SDF4 | c.774C>T p.T258= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs773066042, COSV55418690; called by muse, mutect2, varscan2
- THSD4 | c.42C>T p.F14= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV55980279; called by muse, mutect2, varscan2
- TLE3 | c.246G>A p.A82= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs530193783, COSV58166714; called by mutect2, varscan2
- TRIM16L | c.771G>A p.G257= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs1180331274, COSV67459771; called by muse, mutect2, varscan2
- TUBA3C | c.1116G>A p.Q372= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1468681984, COSV68029370; called by muse, varscan2
- VPS16 | c.1254C>T p.F418= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs368671330; called by muse, mutect2, varscan2
- VWF | c.6288C>T p.F2096= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54630502; called by muse, mutect2, varscan2
- LOXL2 | c.-83-17528C>T | Intron (SNP) | VAF 6/76 reads (8%) | catalogued as COSV62269943; called by muse, mutect2
- SLITRK2 | chrX:145827860 T>A | 3'Flank (SNP) | VAF 11/77 reads (14%) | catalogued as COSV59427836; called by muse, mutect2, varscan2
- XIST | n.7585G>A | RNA (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
